TCGA case TCGA-JW-A5VJ — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f0bb0d18-1190-463d-a0ba-839c2c776794

Demographics
Sex at birth: female; Race: american indian or alaska native; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 56.7 years (20,714 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Brachytherapy, Low Dose; Treatment intent type: Adjuvant; Treatment dose: 4,200 cGy; Treatment outcome: Progressive Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 5,040 cGy; Treatment outcome: Progressive Disease; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, postoperative.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 57.4 years (20,981 days); Days to diagnosis: 267 days; Prior treatment: Yes.

Follow-up (8 entries)
- Day 0 (preoperative): Days to imaging: 0 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 0 (preoperative): Days to imaging: 0 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement.
- Days to follow up: 7 days; ECOG performance status: 2.
- Day 258 (post adjuvant therapy): ECOG performance status: 3.
- Day 267 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to progression: 267 days; Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 401 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 588 days (1.6 years); Disease response: With Tumor.
- Days to follow up: 652 days (1.8 years); Disease response: With Tumor; ECOG performance status: 3.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Timepoint category: Initial Diagnosis; Weight: 57 kg; Height: 155 cm; BMI: 23.7.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JW-A5VJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-JW-A5VJ-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-JW-A5VJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 1; Pregnancies count stillbirth: 0; Total pregnancy count: 3; Tobacco smoking history indicator: 1; Days from index date to performance status: 7; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: No.
- Diagnostic ct result outcomes: Ct scan preop results: Paraaortic Nodes Present; Ct scan preop results: Pelvic Nodes Present.
- Treatment, Radiation therapy info: Brachytherapy type: LDR; Radiation therapy xrt type: External beam radiation.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent type: Cisplatin; Chemo concurrent dose: 40mg/m2; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 5.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Partial Remission/Response.
- Follow-up form 1, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent type: Carboplatin; Chemo concurrent dose: 40mg/m2; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 5.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Performance status other timing: at hospiace.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 652 days; disease-specific survival: no event (censored), 652 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 267 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JW-A5VJ-01A-11D-A28A-01): tumor purity 0.65, ploidy 2.21, whole-genome doublings 0.
